Somatic mutation profile of tumor specimen MP2PRT-PAUJZD-TMP1-A (aliquot MP2PRT-PAUJZD-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUJZD, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,463 days).
Specimen MP2PRT-PAUJZD-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3df0c40-799f-4c66-bed8-17313206b443.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUJZD-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUJZD-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e203c07-bbce-4c45-b2bf-4618e2578d4e

The open-access MAF lists 12 somatic variants for this specimen: 8 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 7, Silent 3, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 43/274 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADAMTS5 | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 458/893 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.812); catalogued as rs766100243, COSV53182969; called by muse, mutect2, varscan2
- CFAP65 | c.625G>A p.V209I | Missense Mutation (SNP) | VAF 76/237 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as rs144290052; called by muse, mutect2, varscan2
- DENND2A | c.2210G>A p.R737Q | Missense Mutation (SNP) | VAF 106/272 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.413); catalogued as rs1454407510; called by muse, mutect2, varscan2
- DNER | c.993G>A p.E331= | Splice Region (SNP) | VAF 74/181 reads (41%) | catalogued as COSV59171257; called by muse, mutect2, varscan2
- MMEL1 | c.1852G>A p.G618S | Missense Mutation (SNP) | VAF 106/339 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs530721264; called by muse, mutect2, varscan2
- DNAH6 | c.10097A>G p.H3366R | Missense Mutation (SNP) | VAF 103/292 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HSPA12A | c.427C>A p.L143M | Missense Mutation (SNP) | VAF 65/219 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- BRWD3 | c.375G>A p.L125= | Silent (SNP) | VAF 109/154 reads (71%) | called by muse, mutect2, varscan2
- PTPN14 | c.2031C>T p.P677= | Silent (SNP) | VAF 58/410 reads (14%) | catalogued as rs770086401, COSV65281347; ClinVar: likely benign; called by muse, varscan2
- SLC49A3 | c.1620G>A p.A540= (on ENST00000404286 / NM_001294341.2; = p.A539= on NM_032219.4) | Silent (SNP) | VAF 73/574 reads (13%) | called by muse, mutect2, varscan2
- RBM44 | c.-98-1972G>A | Intron (SNP) | VAF 21/309 reads (7%) | catalogued as rs369741355; called by muse, mutect2
